TCGA case TCGA-CS-6665 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c16d9f69-26f9-4ec7-b2d5-ff9f7dacfe0f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,977 days); Year of diagnosis: 2010; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,568 days (4.3 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 250; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 69 days; Treatment dose: 59 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Prior malignancy of the breast (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Day -1 (preoperative): Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 378 days (1.0 years); Disease response: With Tumor.
- Days to follow up: 1,568 days (4.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies; Risk factors: Allergy, Nuts.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CS-6665-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-CS-6665-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-CS-6665-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-CS-6665-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CS-6665-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: Yes; Allergy food diagnosis type: Hazelnuts; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 1: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -98.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy breast cancer treated with radiation.
- Prior malignancy: Prior malignancy breast cancer treated with radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,568 days; disease-specific survival: no event (censored), 1,568 days; progression-free interval: no event (censored), 1,568 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CS-6665-01A-11D-1892-01): tumor purity 0.61, ploidy 3.39, whole-genome doublings 1.
